Surgical pathology report (de-identified scan), TCGA case TCGA-14-0789, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0789-01A (Primary Tumor).

[page 1 of 2]
= Section 1 of 1: Anatomic Pathology Report

= Auth [REDACTED] EMR EVENT Id: [REDACTED]

Patient: [REDACTED]

Accession Number: [REDACTED]

Patient Number: [REDACTED]

Date Collected: [REDACTED]

Financial Number: [REDACTED]

Date Received: [REDACTED]

Room/Bed: [REDACTED]

PT: [REDACTED]

Admitting Physician: [REDACTED]

Ordering Physician: [REDACTED]

14-0789

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN TUMOR, BIOPSY, FS1A, TP1A:
- NECROTIC TISSUE.
2. BRAIN TUMOR, BIOPSY AND EXCISION, FS2A, TP2A:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).
3. BRAIN TUMOR, EXCISION:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

SPECIMEN:

1. Brain tumor.
2. Brain tumor.
3. Brain tumor.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Right craniotomy. Right brain mass.

GROSS DESCRIPTION:

Received are three specimens. Specimens #1-2 are received fresh for intraoperative consultation and specimen #3 is received in formalin, each labeled with the patient's name and medical record number.

Specimen #1 is labeled "brain tumor." The specimen consists of several fragments of tan-red tissue, measuring 1.1 x 0.8 x 0.3 cm in aggregate. A touch smear was made. A representative section of the specimen is submitted for intraoperative consultation and the remainder of the specimen is submitted entirely in cassette "FS1A." The remainder of the specimen is submitted in cassette "1B."

Specimen #2 is labeled "brain tumor." The specimen consists of several fragments of tan-red tissue, measuring 1.5 x 1.2 x 0.3 cm in aggregate. A touch smear was made. Representative sections of the specimen are submitted for frozen section consultation and the remainder of the cryoblock is submitted in its entirety in cassette "FS2A." The remainder of the specimen is submitted entirely in cassette "2B."

[page 2 of 2]
Specimen #3 is labeled "brain tumor." The specimen consists of a fragment of brain parenchyma measuring 5.2 x 3.1 x 1.6 cm. One aspect of the tissue is raggy and hemorrhagic and possibly represents the surgical margin of resection. A separate fragment representing a blood clot measuring 1.8 x 1.5 x 0.4 cm is identified. Representative sections of the specimen are submitted as follows:

CODE OF MICROSCOPIC SECTIONS:

3A-C: Representative sections of the brain parenchyma
3D: Blood clot

14-0789

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: BRAIN TUMOR, RIGHT MASS, BIOPSY (FROZEN SECTION, TOUCH PREPARATION): NECROTIC TISSUE.

FS2A, TP2A: BRAIN TUMOR, RIGHT BRAIN MASS, BIOPSY (FROZEN SECTION, TOUCH PREPARATION): GLIOBLASTOMA MULTIFORME.

Patient: [REDACTED]
Patient Number: [REDACTED]

Accession Number: [REDACTED]

SURGICAL PATHOLOGY REPORT

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

Source: NCI Genomic Data Commons file 40f6a16b-bb2b-4569-a128-5cd883f101cb (TCGA-14-0789.ED9F8678-240B-4029-8BC4-A73103B56CF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).